Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A51R, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A51R-06A (Metastatic).

DIAGNOSIS

- (A) LYMPH NODES LEFT AXILLA LEVELS 1-3:
MELANOMA METASTATIC TO ADIPOSE TISSUE
TUMOR SIZE: 40 X 40 MM
Tumor borders pushing
A completely replaced lymph node is not ruled out

Additional eleven lymph node(s), negative for melanoma (0/11).

- (B) LYMPH NODES LEFT AXILLA, ADDITIONAL LEVEL 3:
Four lymph node(s), negative for melanoma (0/4).

1CD-0-3

Melanoma NOS 8720/3

Site: lymph node, axilla C49.3

fw
11/6/12

GROSS DESCRIPTION

(A) LEFT AXILLARY MASS AND CONTENTS, LEVEL 1, 2 AND 3 – An (11.0 x 7.5 x 2.5 cm) portion of fibroadipose tissue which yields multiple possible lymph nodes ranging from 0.2 to 4.0 cm in greatest dimension. The largest lymph node is grossly positive. The majority of this lymph node is submitted to studies and tumor bank. The lymph nodes are submitted as follows:

SECTION CODE: A1, four lymph nodes; A2, four lymph nodes; A3, two lymph nodes; A4, one lymph node, serially sectioned; A5, one grossly positive lymph node.

(B) ADDITIONAL LEFT AXILLARY CONTENTS LEVEL 3 – A 4.0 x 3.3 x 0.5 cm aggregate of fibroadipose tissue. The tissue is dissected to reveal four possible lymph nodes ranging from 0.2 x 0.2 x 0.2 cm – 0.5 x 0.3 x 0.2 cm.

SECTION CODE: B, four possible lymph nodes.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

M-87206, M-00110 M-00110

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by.

-----END OF REPORT-----

HPOAA Discrepancy		
Re-lever Tumor		

BTH 11/5/12

Source: NCI Genomic Data Commons file a952188e-a6b2-4dd4-8b96-e2e3997e6407 (TCGA-D3-A51R.522EF4E5-0C5E-46C3-9A41-D38EBCD8A817.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).